Somatic mutation profile of tumor specimen BA2586D (aliquot aq-BA2586D) from BEATAML1.0 case 2534, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.2 years (21,251 days).
Specimen BA2586D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79c1885f-c9f5-4c66-86c0-a38d5525ea93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2601D (Solid Tissue Normal), aliquot aq-BA2601D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c25247e7-5d2a-4f14-a8bc-1db95d924e45

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, 5'UTR 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60705468; called by muse, mutect2
- NOL8 | c.1943_1946del p.Q648Pfs*28 | Frame Shift Del (DEL) | VAF 24/131 reads (18%) | catalogued as rs763568326; called by pindel, varscan2
- AEBP2 | c.303-2A>C p.X101_splice | Splice Site (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- CPNE5 | c.1465G>T p.G489C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LARP7 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFAF7 | c.709T>G p.F237V | Missense Mutation (SNP) | VAF 57/395 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM202 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ACTL7A | c.54C>A p.G18= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- BRPF3 | c.1947C>T p.R649= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as rs1332152665; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1417T>C p.L473= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs1244232414; called by muse, mutect2, varscan2
- IGF2BP3 | c.264C>T p.I88= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs759196689; called by muse, mutect2
- RAB34 | c.-67G>T | 5'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- SPATA20 | c.-4A>G | 5'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2
